TCGA case TCGA-EK-A2RM — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c13215d9-26a8-4c8b-b4fe-5da6aa3222af

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 40.6 years (14,842 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; FIGO stage: Stage IB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 36; Lymphatic invasion present: Yes.

Follow-up (2 entries)
- Day 0 (preoperative): ECOG performance status: 1.
- Days to follow up: 50 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Weight: 105 kg; Height: 167 cm; BMI: 37.6.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A2RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 100 mg.
  Slide TCGA-EK-A2RM-01A-02-TS2: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EK-A2RM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 4; Total pregnancy count: 4; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Radical Hysterectomy, BSO; Lymph nodes examined: Yes; Lymphovascular invasion: Present.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 50 days; disease-specific survival: no event (censored), 50 days; progression-free interval: no event (censored), 50 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A2RM-01A-21D-A18H-01): tumor purity 0.65, ploidy 3.51, whole-genome doublings 1.
